MMRF case MMRF_2364 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ab6678eb-ce53-4e9c-bbb5-749334674333

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 51 years; Vital status: Dead; Days to death: 156 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 51.5 years (18,821 days); ISS stage: III; Days to last known disease status: 156 days; Days to last follow up: 156 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 156 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 156.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -8 (ECOG 0): M Protein 5.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 294 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.113 mg/dL; Immunoglobulin G 72.9 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.135 g/L; Beta 2 Microglobulin 6.7 µg/mL; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 5.85 ×10⁹/L; Absolute Neutrophil 2.82 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 94.6 µmol/L; Calcium 2.18 mmol/L; Albumin 32 g/L; Total Protein 11.2 g/dL; Glucose 5.39 mmol/L; C-Reactive Protein 0.488 mg/dL.
- Day 90 (ECOG 3): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.073 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.78 mg/dL; Immunoglobulin G 8.02 g/L; Immunoglobulin A 0.135 g/L; Immunoglobulin M 0.492 g/L; Beta 2 Microglobulin 1.4 µg/mL; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 9.77 ×10⁹/L; Absolute Neutrophil 6.75 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 30.9 µmol/L; Calcium 2.2 mmol/L; Albumin 34 g/L; Total Protein 5.4 g/dL; Glucose 6.71 mmol/L.

Other clinical attributes
- Day -8: Weight: 102 kg; Height: 164 cm.

Family history
- Relative with cancer history: yes; Relationship type: Paternal Grandfather; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2364_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -8 days.
- Sample MMRF_2364_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -8 days.
